Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1XK, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1XK-01A (Primary Tumor).

Department of Cancer Pathology

copy No. .

Date: .

Examination: Histopathological examination

Internal invoice No.

Value of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: 1. Multiple organ resection - left breast with axillary tissues

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the left breast.

ICB-0-3

carcinoma, infiltrating duct, nos 8500/3
Site: breast, nos 050.9 hr 4/12/11

Examination performed on:

Macroscopic description:

Left breast sized 16.8 x 15.3 x 5.2 cm removed along with axillary tissues sized 10 x 6 x 5 cm and a 16.2 x 9.8 cm skin flap and a fragment of the muscle sized 4 x 3 cm. Weight 620 g.

Tumour sized 3.5 x 3 x 3 cm found in the inner upper quadrant, 1 cm from the inner boundary, 0.2 cm from the base and 0.8 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum - NHG3 (3+3+3/36 mitoses/10 HPF - visual area: 0.55mm²)

Mamilla sine laesionibus.

Glandular tissue with lesions of the type mastopathia fibrosa and cystica.

Invasive lesions 0.1 cm away from the base.

Axillary lymph nodes:

Metastases carcinomatosae in lymphonodis (No III/XVIII).

Histopathological diagnosis:

Carcinoma invasivum mammae sinistae. Invasive ductal carcinoma of the left breast.

Metastases carcinomatosae in lymphonodis axillae (NHG3, pT2, pN1a). Cancer metastases in axillary lymph nodes.

Compliance validated by:

Examination performed on:

Results of immunohistochemical examination:

No estrogen receptors found in neoplastic cell nuclei.

No progesterone receptors found in neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive carcinoma cells (Score = 0).

Compliance validated by: .

CONTACT YOUR DOCTOR WITH THIS REPORT!

Case is (single):	CHANGED	DISQUALIFIED

Source: NCI Genomic Data Commons file 028b6a76-166f-48d7-a47c-11e50f53ab71 (TCGA-D8-A1XK.B3DB4F9E-C91B-4913-93E8-F18FF22CBA7C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).